CPTAC case C3L-03678 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/58447c8d-2e24-4f06-b477-c8a5785ed852

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1968; Vital status: Dead; Days to death: 485 days (1.3 years); Year of death: 2019; Cause of death: Infection; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 49.9 years (18,220 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 485 days (1.3 years); Days to last follow up: 485 days (1.3 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm (a second GDC size field records 3.8 cm); Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 18; Margin status: Uninvolved.

Follow-up (2 entries)
- Days to follow up: 398 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 485 days (1.3 years); Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 108.86 kg; Height: 172.72 cm; BMI: 36.49.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 70; Cigarettes per day: 40; Tobacco smoking onset year: 1982; Tobacco smoking quit year: 2017; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 35; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03678-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 174 mg; Time between excision and freezing: 29 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03678-21: Section location: Left Lower Lobe; Percent tumor nuclei: 80; Percent necrosis: 3.
- Sample C3L-03678-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -7 days; Method of sample procurement: Blood Draw.
